Somatic mutation profile of tumor specimen TCGA-IE-A4EJ-01A (aliquot TCGA-IE-A4EJ-01A-11D-A24N-09) from TCGA case TCGA-IE-A4EJ, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Giant cell sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 84.5 years (30,858 days).
Specimen TCGA-IE-A4EJ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) baff86e3-0082-464a-8abe-bf0cd5082571.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-IE-A4EJ-10A (Blood Derived Normal), aliquot TCGA-IE-A4EJ-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ed1349e-e828-4f4e-8a23-98f762b30d41

The open-access MAF lists 60 somatic variants for this specimen: 41 protein-altering or splice-affecting, 17 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 35, Silent 17, Nonsense Mutation 3, Frame Shift Del 1, Splice Site 1, Splice Region 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.638G>C p.R213P | Missense Mutation (SNP) | VAF 35/57 reads (61%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587778720, CM004906, CM022474, COSV52665093, COSV52668963, COSV52693072; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADGRL2 | c.407G>A p.C136Y | Missense Mutation (SNP) | VAF 19/122 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.969); catalogued as COSV99591969; called by muse, mutect2, varscan2
- AOX1 | c.3124C>T p.H1042Y | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs764479130, COSV99613811; called by muse, mutect2, varscan2
- ATP1A3 | c.592G>T p.G198C (on ENST00000545399 / NM_001256214.2; = p.G185C on NM_152296.5) | Missense Mutation (SNP) | VAF 32/85 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.42); catalogued as COSV100132616; called by muse, mutect2, varscan2
- ATRX | c.5638A>T p.S1880C | Missense Mutation (SNP) | VAF 18/103 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100971606; called by muse, mutect2, varscan2
- ATRX | c.4246C>T p.Q1416* | Nonsense Mutation (SNP) | VAF 17/30 reads (57%) | catalogued as COSV100971607; called by muse, mutect2, varscan2
- CACNA1D | c.5516del p.C1839Sfs*115 (on ENST00000350061 / NM_001128840.3; = p.C1859Sfs*115 on NM_000720.4) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | catalogued as rs765123480; called by mutect2, pindel, varscan2
- CADM1 | c.1312A>G p.K438E | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); catalogued as COSV100523580; called by muse, mutect2
- CNKSR2 | c.2415G>T p.R805S | Missense Mutation (SNP) | VAF 16/111 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.711); catalogued as COSV99670128; called by muse, mutect2, varscan2
- CYLC1 | c.976G>A p.V326I | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.073); catalogued as COSV100255620; called by muse, mutect2
- CYP2C9 | c.857G>T p.S286I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as COSV99583336; called by muse, mutect2, varscan2
- FBXW5 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.312); catalogued as rs1253966855, COSV99812708; called by muse, mutect2, varscan2
- GPR19 | c.306C>G p.Y102* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV100197015; called by muse, mutect2, varscan2
- KALRN | c.8369C>A p.A2790D (on ENST00000360013 / NM_001024660.4; = p.A1093D on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99363181; called by muse, mutect2, varscan2
- KCNH4 | c.1736C>A p.P579Q | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52921449, COSV52921524; called by muse, mutect2
- KIF1A | c.2509G>A p.G837R | Missense Mutation (SNP) | VAF 24/60 reads (40%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs768702963, COSV100242552, COSV57485318; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- L1CAM | c.1198A>G p.M400V | Missense Mutation (SNP) | VAF 26/105 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as CD011871, COSV100649523; called by muse, mutect2, varscan2
- LAMB1 | c.458C>T p.S153L | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774870882, COSV55964026, COSV55964780; called by muse, mutect2, varscan2
- LINGO2 | c.1271A>T p.E424V | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100431346; called by muse, mutect2, varscan2
- MRGPRX3 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 22/256 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); catalogued as rs572680080, COSV101283594, COSV66934487; called by muse, mutect2
- OR5V1 | c.381C>A p.C127* | Nonsense Mutation (SNP) | VAF 5/54 reads (9%) | catalogued as COSV101011516; called by muse, mutect2
- PCDHA7 | c.1765C>A p.H589N | Missense Mutation (SNP) | VAF 30/141 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.089); catalogued as COSV100971939; called by muse, mutect2, varscan2
- PIM2 | c.400C>A p.P134T | Missense Mutation (SNP) | VAF 23/89 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.027); catalogued as COSV99900632; called by muse, mutect2, varscan2
- PLEKHG6 | c.2294T>G p.L765R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99165141; called by muse, mutect2, varscan2
- POU4F2 | c.288G>A p.P96= | Splice Region (SNP) | VAF 8/43 reads (19%) | catalogued as rs776901796, COSV55583664; called by muse, mutect2, varscan2
- PRR27 | c.52-1G>C p.X18_splice | Splice Site (SNP) | VAF 5/86 reads (6%) | catalogued as COSV100748920; called by muse, mutect2
- RAB18 | c.259G>C p.V87L | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV100803907; called by muse, mutect2, varscan2
- RAB39B | c.404G>A p.R135H | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.596); catalogued as COSV101035060; called by muse, mutect2, varscan2
- RASGRF2 | c.3305G>T p.R1102I | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV54123994, COSV54134192, COSV99430793; called by muse, mutect2
- RBM3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV100618790; called by muse, mutect2, varscan2
- RPL7 | c.517G>A p.A173T | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs777899375, COSV53584210; called by muse, mutect2, varscan2
- SFMBT2 | c.241G>A p.E81K | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62814054; called by muse, mutect2, varscan2
- STYXL2 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.499); catalogued as rs758006721, COSV54804983; called by muse, mutect2
- TRHDE | c.599T>C p.F200S | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV99673008; called by muse, mutect2
- TTC21A | c.2396G>A p.C799Y | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.272); catalogued as COSV100087771; called by muse, mutect2, varscan2
- TTLL13P | c.590G>A p.R197H | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV60039988; called by muse, mutect2, varscan2
- TXNRD1 | c.346G>T p.A116S (on ENST00000525566 / NM_001093771.3; = p.A18S on NM_003330.4) | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV100723610, COSV61597908; called by muse, mutect2, varscan2
- WWP1 | c.2388A>T p.E796D | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99617407; called by muse, mutect2, varscan2
- ZBTB46 | c.455G>A p.S152N | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as COSV99829768; called by muse, mutect2, varscan2
- ZNF99 | c.1265A>G p.E422G | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV101233998; called by muse, mutect2, varscan2
- IGLV3-27 | c.202A>G p.K68E | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.95); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- C9orf72 | c.171A>G p.G57= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as COSV101186568; called by muse, mutect2
- CACNA1H | c.4710G>A p.A1570= | Silent (SNP) | VAF 20/77 reads (26%) | catalogued as rs759616283, COSV61987070; ClinVar: likely benign; called by muse, mutect2, varscan2
- FAM47B | c.465C>A p.P155= | Silent (SNP) | VAF 15/151 reads (10%) | catalogued as COSV61452745, COSV61455558; called by muse, mutect2
- GIMAP8 | c.1677C>T p.Y559= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV56231721; called by muse, mutect2, varscan2
- KSR2 | c.555G>A p.P185= | Silent (SNP) | VAF 47/126 reads (37%) | catalogued as rs373628463; called by muse, mutect2, varscan2
- LRRC30 | c.102G>T p.L34= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV101274470; called by muse, mutect2, varscan2
- LYSMD4 | c.180C>A p.V60= (on ENST00000409796 / NM_001284417.2; = p.S31Y on NM_152449.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 9/192 reads (5%) | catalogued as COSV100230583, COSV100230750; called by muse, mutect2
- MYH9 | c.5811A>G p.K1937= | Silent (SNP) | VAF 58/80 reads (73%) | catalogued as rs757593797, COSV99339996; called by muse, mutect2, varscan2
- NOTCH3 | c.5388T>C p.A1796= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV99659203; called by muse, mutect2, varscan2
- OR10K1 | c.24G>A p.V8= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as COSV99194062; called by muse, mutect2, varscan2
- OR4A47 | c.75T>A p.L25= | Silent (SNP) | VAF 53/105 reads (50%) | catalogued as COSV101487120; called by muse, mutect2, varscan2
- OR5L1 | c.93C>T p.F31= | Silent (SNP) | VAF 22/90 reads (24%) | catalogued as rs1247996381, COSV100450285; called by muse, mutect2, varscan2
- PGC | c.843G>T p.L281= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as COSV57825529; called by muse, mutect2
- RPH3A | c.1581C>A p.T527= (on ENST00000389385 / NM_001143854.2; = p.T523= on NM_014954.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/68 reads (35%) | catalogued as rs1281582668, COSV66992599; called by muse, mutect2, varscan2
- TET3 | c.441G>A p.R147= | Silent (SNP) | VAF 15/69 reads (22%) | catalogued as COSV99996652; called by muse, mutect2, varscan2
- TUBB2A | c.423C>T p.G141= | Silent (SNP) | VAF 9/97 reads (9%) | catalogued as rs555332069; ClinVar: likely benign; called by muse, mutect2, varscan2
- TULP4 | c.3456T>A p.S1152= | Silent (SNP) | VAF 16/72 reads (22%) | catalogued as COSV100893891; called by muse, mutect2, varscan2
- FADS2 | c.-1C>T | 5'UTR (SNP) | VAF 9/36 reads (25%) | catalogued as rs762478718, COSV99609215; called by muse, mutect2, varscan2
- MIR369 | n.65T>C | RNA (SNP) | VAF 4/39 reads (10%) | called by muse, mutect2
